Somatic mutation profile of tumor specimen MP2PRT-PASZLL-TMP1-A (aliquot MP2PRT-PASZLL-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASZLL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,659 days).
Specimen MP2PRT-PASZLL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4771a37-5b3d-45a8-a6bf-19aca9c6e1fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZLL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZLL-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f54be1c2-dd11-4560-8fa1-a45f81902a30

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 13, Frame Shift Ins 2, Nonsense Mutation 2, RNA 2, In Frame Ins 1, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880471; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763091056, COSV54634486; called by muse, mutect2, varscan2
- ARHGAP17 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 58/529 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV51504866; called by muse, mutect2, varscan2
- ARHGAP21 | c.5569C>T p.R1857C | Missense Mutation (SNP) | VAF 124/478 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs774267791; called by muse, mutect2, varscan2
- BGN | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 335/740 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV59038388; called by muse, mutect2, varscan2
- CC2D1B | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 78/558 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as rs202004301; called by muse, mutect2, varscan2
- FSTL5 | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 15/486 reads (3%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV100053115, COSV60187786; called by muse, mutect2
- NTPCR | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64052115; called by muse, mutect2, varscan2
- NTSR2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 120/717 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100183829, COSV60991472; called by muse, mutect2, varscan2
- NUP160 | c.4300C>T p.R1434W | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs764848797; called by muse, mutect2, varscan2
- PKD1 | c.6440G>A p.R2147Q | Missense Mutation (SNP) | VAF 103/629 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs771035065; called by muse, mutect2, varscan2
- PTPRF | c.3527G>A p.R1176Q | Missense Mutation (SNP) | VAF 80/687 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs772418794; called by muse, mutect2, varscan2
- QRFPR | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 113/434 reads (26%) | catalogued as rs989174472, COSV57676413; called by muse, mutect2, varscan2
- RBM44 | c.227C>T p.S76L (on ENST00000611254; = p.S710L on NM_001080504.2) | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs373599531; called by muse, mutect2, varscan2
- ROS1 | c.5092G>C p.E1698Q | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.903); catalogued as COSV100877222; called by muse, mutect2, varscan2
- RSPO2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 152/570 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs182334537, COSV52639993; called by muse, mutect2, varscan2
- SCLT1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 86/487 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99827799; called by muse, mutect2, varscan2
- SHKBP1 | c.1598C>G p.S533C | Missense Mutation (SNP) | VAF 66/383 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs1227086208; called by muse, mutect2, varscan2
- SLC29A2 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 92/402 reads (23%) | catalogued as rs767090901, COSV60803263; called by muse, mutect2, varscan2
- SLIT3 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 147/635 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.499); catalogued as rs750966680, COSV60592695; called by muse, mutect2, varscan2
- SORCS2 | c.3046G>T p.D1016Y | Missense Mutation (SNP) | VAF 112/487 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61171167; called by muse, mutect2, varscan2
- TBC1D25 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 103/737 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs1556985530, COSV100952156, COSV65124309; called by muse, mutect2, varscan2
- TRPA1 | c.699C>G p.N233K | Missense Mutation (SNP) | VAF 177/405 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51571613; called by muse, mutect2, varscan2
- TRPC6 | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs199503731; called by muse, mutect2, varscan2
- USF3 | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 109/484 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377383163; called by muse, mutect2, varscan2
- C17orf78 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, varscan2
- CHD1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 56/398 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, varscan2
- DEPDC5 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DHX37 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 62/527 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- FCHO2 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); called by muse, mutect2
- FSIP2 | c.20390C>T p.S6797F | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- IDH3B | c.99C>G p.H33Q | Missense Mutation (SNP) | VAF 79/626 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV4-59 | c.341_349del p.C114_R116del | In Frame Del (DEL) | VAF 3/18 reads (17%) | called by mutect2, pindel*
- IGHV4-61 | chr14:106639118 GTCTCTCGCAC>CCCAGT | Missense Mutation (DEL) | VAF 18/41 reads (44%) | called by pindel, varscan2*
- IGKV2D-30 | c.359_360insCCGC p.*121Rfs*? | Frame Shift Ins (INS) | VAF 34/65 reads (52%) | called by mutect2, varscan2
- IGKV2D-30 | c.360delinsCCGCC p.*121Rfs*? | Frame Shift Ins (INS) | VAF 45/63 reads (71%) | called by mutect2*, pindel, varscan2*
- IMMT | c.807G>C p.K269N | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); called by muse, mutect2
- LANCL2 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 92/683 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LMOD2 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 100/647 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- LMTK2 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 102/554 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- METTL7B | c.499-1G>A p.X167_splice | Splice Site (SNP) | VAF 50/255 reads (20%) | called by muse, mutect2, varscan2
- MLNR | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 74/592 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH2 | c.3121G>C p.E1041Q | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, varscan2
- MYO18A | c.5557G>C p.E1853Q | Missense Mutation (SNP) | VAF 57/443 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NELFA | c.217_218insCGC p.L72_H73insP (on ENST00000542778; = p.L61_H62insP on NM_005663.5) | In Frame Ins (INS) | VAF 110/536 reads (21%) | called by mutect2, pindel, varscan2
- PHF14 | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RPIA | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A9 | c.1932G>C p.L644F (on ENST00000360584 / NM_201649.4; = p.L590F on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SVOP | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.762); called by muse, mutect2
- SYCP2L | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- UBA2 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UCP3 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 116/474 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ARHGAP39 | c.462G>A p.A154= | Silent (SNP) | VAF 76/660 reads (12%) | catalogued as rs1272951225; called by muse, mutect2, varscan2
- AZI2 | c.504G>A p.K168= | Silent (SNP) | VAF 92/522 reads (18%) | called by muse, mutect2, varscan2
- CCDC148 | c.1602C>T p.F534= | Silent (SNP) | VAF 28/290 reads (10%) | called by muse, mutect2
- COL20A1 | c.2547C>T p.F849= | Silent (SNP) | VAF 50/388 reads (13%) | catalogued as rs1283870027; called by muse, varscan2
- DBH | c.957C>T p.F319= | Silent (SNP) | VAF 61/448 reads (14%) | catalogued as rs368420701; called by muse, mutect2, varscan2
- DNAH17 | c.930C>T p.F310= | Silent (SNP) | VAF 36/506 reads (7%) | catalogued as rs1402654268, COSV67760709; called by muse, mutect2
- F2 | c.310C>T p.L104= | Silent (SNP) | VAF 157/371 reads (42%) | called by muse, mutect2, varscan2
- FLRT1 | c.690C>T p.D230= | Silent (SNP) | VAF 262/557 reads (47%) | catalogued as rs377387995; called by muse, mutect2, varscan2
- LRRC39 | c.408C>T p.L136= | Silent (SNP) | VAF 54/367 reads (15%) | catalogued as COSV61583086; called by muse, mutect2, varscan2
- MAMDC4 | c.219C>T p.C73= | Silent (SNP) | VAF 265/609 reads (44%) | catalogued as rs372601594; called by muse, mutect2, varscan2
- MYH6 | c.1323G>A p.V441= | Silent (SNP) | VAF 84/680 reads (12%) | called by muse, mutect2, varscan2
- RNF170 | c.543G>C p.L181= | Silent (SNP) | VAF 42/364 reads (12%) | catalogued as COSV53566977; called by muse, mutect2, varscan2
- UPK1B | c.129C>G p.L43= | Silent (SNP) | VAF 17/547 reads (3%) | catalogued as rs1559901929; called by muse, mutect2
- AC010186.2 | n.401_402insGGC | RNA (INS) | VAF 117/476 reads (25%) | called by mutect2, pindel, varscan2
- BTBD11 | c.1491-157C>G | Intron (SNP) | VAF 69/300 reads (23%) | called by muse, mutect2, varscan2
- XIST | n.10226A>C | RNA (SNP) | VAF 50/331 reads (15%) | called by muse, varscan2
